Somatic mutation profile of tumor specimen C3N-00494-02 (aliquot CPT0012900010) from CPTAC case C3N-00494, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.0 years (24,122 days).
Specimen C3N-00494-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91cee412-ce96-4a69-a9b8-afa4ef5a1144.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00494-31 (Blood Derived Normal), aliquot CPT0012980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/689c66c0-3764-4a8a-9839-254f723d97eb

The open-access MAF lists 108 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 21, Frame Shift Del 7, Intron 4, Nonsense Mutation 4, 3'UTR 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1, RNA 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 135/382 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691439, COSV63973975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.3035G>T p.R1012M | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as COSV99270800; called by muse, mutect2
- AMER1 | c.3308G>T p.G1103V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV57662101; called by muse, mutect2
- BCDIN3D | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 28/278 reads (10%) | catalogued as COSV61702721; called by muse, mutect2, varscan2
- FAM13A | c.1390A>C p.S464R | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52008762; called by muse, mutect2, varscan2
- IL20RA | c.1381G>C p.A461P | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1243457821; called by muse, mutect2, varscan2
- KCNA2 | c.317del p.L106* | Frame Shift Del (DEL) | VAF 117/372 reads (31%) | catalogued as COSV100316076; called by mutect2, pindel, varscan2
- KCTD8 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1243506439; called by muse, mutect2, varscan2
- LRRC1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV63823304; called by muse, mutect2, varscan2
- MIA | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs577492559, COSV54572702; called by muse, mutect2
- NECTIN1 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV99871879; called by muse, varscan2
- OR14A2 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100825528; called by muse, mutect2, varscan2
- PITPNM3 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs941922159; called by muse, mutect2, varscan2
- PLCB1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as COSV62046201; called by muse, mutect2, varscan2
- SIGIRR | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 51/202 reads (25%) | catalogued as rs778148546, COSV58985876; called by muse, mutect2, varscan2
- SLC19A3 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as CM131528; called by muse, mutect2, varscan2
- SYTL3 | c.1266C>G p.D422E (on ENST00000611299 / NM_001242394.1; = p.D354E on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV51914685; called by muse, mutect2, varscan2
- TGFB2 | c.1008C>A p.H336Q | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100860362; called by muse, mutect2
- TMEM232 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV101459900; called by muse, mutect2, varscan2
- TSNAXIP1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs746465595; called by muse, mutect2
- TTN | c.7720C>G p.P2574A (on ENST00000591111; = p.P2528A on NM_003319.4) | Missense Mutation (SNP) | VAF 23/301 reads (8%) | PolyPhen benign (0); catalogued as COSV59931673; called by muse, mutect2
- VHL | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 115/292 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as CM023999, CS951541, COSV56543854, COSV56544010, COSV56545833; called by muse, mutect2, varscan2
- ADAMTS2 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 112/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ANKRD10 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 70/237 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BCOR | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 124/190 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BRF2 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 165/497 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- C2orf78 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2
- C3 | c.4815G>T p.W1605C | Missense Mutation (SNP) | VAF 199/631 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNGA1 | c.528G>T p.W176C | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- COL9A1 | c.734T>G p.L245R | Missense Mutation (SNP) | VAF 157/424 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL5 | c.554-9_567del p.X185_splice | Splice Site (DEL) | VAF 24/95 reads (25%) | called by mutect2, pindel
- DNAAF3 | c.1180A>G p.I394V (on ENST00000524407 / NM_001256715.2; = p.I441V on NM_178837.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAI2 | c.1766A>G p.E589G | Missense Mutation (SNP) | VAF 116/456 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELN | c.1556T>G p.I519S | Missense Mutation (SNP) | VAF 219/802 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EXOC2 | c.2725T>A p.L909M | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- EXOC2 | c.2724C>A p.H908Q | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCN3 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FSIP2 | c.14408C>T p.S4803F | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- GPR75 | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GREB1L | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GRK7 | c.375_376del p.L126Qfs*14 | Frame Shift Del (DEL) | VAF 14/103 reads (14%) | called by mutect2, pindel, varscan2
- ITGAX | c.1390T>A p.S464T | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2
- KATNB1 | c.1706G>C p.S569T | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KATNB1 | c.1708A>G p.K570E | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- KMT2C | c.247del p.T83Qfs*22 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | called by pindel, varscan2
- KRTAP11-1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- L3MBTL1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LYPLA2 | c.428del p.V143Gfs*3 | Frame Shift Del (DEL) | VAF 50/177 reads (28%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.2753G>A p.G918D | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MBD6 | c.1355A>T p.Q452L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MEX3B | c.1051C>G p.P351A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MINDY1 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MKS1 | c.16T>A p.W6R | Missense Mutation (SNP) | VAF 109/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MUC19 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2
- MYLK | c.4494T>G p.Y1498* | Nonsense Mutation (SNP) | VAF 150/471 reads (32%) | called by muse, mutect2, varscan2
- NRK | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUGGC | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCA2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 104/291 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBRM1 | c.1682del p.I561Tfs*8 | Frame Shift Del (DEL) | VAF 113/260 reads (43%) | called by mutect2, pindel, varscan2
- PTPN13 | c.6840del p.I2280Mfs*17 (on ENST00000411767 / NM_080683.3; = p.I2261Mfs*17 on NM_006264.3) | Frame Shift Del (DEL) | VAF 61/194 reads (31%) | called by mutect2, pindel, varscan2
- RAB36 | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASD1 | c.479_482dup p.E161Dfs*224 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- RMND5B | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SALL3 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SNAP29 | c.565T>A p.Y189N | Missense Mutation (SNP) | VAF 136/424 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SORCS3 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SPRED1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- STPG1 | c.532del p.R178Efs*23 (on ENST00000337248 / NM_001199013.2; = p.R131Efs*23 on NM_178122.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/142 reads (18%) | called by mutect2, pindel, varscan2
- SUDS3 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TACR1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TBX22 | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 42/223 reads (19%) | called by muse, mutect2, varscan2
- TCEAL4 | c.306T>A p.S102R | Missense Mutation (SNP) | VAF 88/123 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.14998C>T p.Q5000* (on ENST00000591111; = p.Q4073* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- ULK1 | c.1155T>C p.S385= | Splice Region (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- USP34 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ZBED1 | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF707 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- A1CF | c.984C>G p.T328= | Silent (SNP) | VAF 101/301 reads (34%) | called by muse, mutect2, varscan2
- GFM1 | c.897C>T p.S299= | Silent (SNP) | VAF 44/269 reads (16%) | catalogued as rs763546447, COSV51833240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLUL | c.963C>T p.A321= | Silent (SNP) | VAF 245/496 reads (49%) | catalogued as rs770429686; called by muse, mutect2, varscan2
- GRID2IP | c.120C>G p.A40= | Silent (SNP) | VAF 49/319 reads (15%) | catalogued as rs937048848; called by muse, mutect2, varscan2
- HHLA1 | c.720C>G p.T240= | Silent (SNP) | VAF 76/209 reads (36%) | called by muse, mutect2, varscan2
- KIF20B | c.4479T>A p.R1493= (on ENST00000371728 / NM_001284259.2; = p.R1453= on NM_016195.4) | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- L3HYPDH | c.315C>T p.G105= | Silent (SNP) | VAF 69/166 reads (42%) | catalogued as rs1426392566; called by muse, mutect2, varscan2
- LRRC70 | c.606T>C p.H202= | Silent (SNP) | VAF 121/407 reads (30%) | called by muse, mutect2, varscan2
- MAP6 | c.1185G>A p.R395= | Silent (SNP) | VAF 45/338 reads (13%) | called by muse, mutect2, varscan2
- MC2R | c.567C>T p.I189= | Silent (SNP) | VAF 66/186 reads (35%) | catalogued as rs267605119, COSV59617516; called by muse, mutect2, varscan2
- MEX3B | c.1200A>C p.A400= | Silent (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- OSBPL3 | c.120A>G p.G40= | Silent (SNP) | VAF 70/211 reads (33%) | called by muse, mutect2, varscan2
- PWWP2B | c.747G>T p.R249= | Silent (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- RGMA | c.375C>T p.R125= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV61235389; called by muse, mutect2, varscan2
- RPTOR | c.2226G>A p.L742= | Silent (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- SMPD3 | c.1005A>T p.A335= | Silent (SNP) | VAF 37/147 reads (25%) | called by muse, mutect2, varscan2
- SNX2 | c.27G>A p.P9= | Silent (SNP) | VAF 47/154 reads (31%) | called by muse, mutect2, varscan2
- SORCS3 | c.876G>T p.R292= | Silent (SNP) | VAF 24/207 reads (12%) | catalogued as COSV100865649, COSV63826086; called by muse, mutect2, varscan2
- SPTA1 | c.3102G>A p.L1034= | Silent (SNP) | VAF 61/495 reads (12%) | called by muse, mutect2, varscan2
- WDR87 | c.6990C>T p.S2330= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1425307857; called by muse, mutect2, varscan2
- ZACN | c.825C>A p.L275= | Silent (SNP) | VAF 52/225 reads (23%) | called by muse, mutect2, varscan2
- AC011525.1 | n.866del | RNA (DEL) | VAF 23/211 reads (11%) | called by mutect2, pindel, varscan2
- ALX4 | c.*26C>G | 3'UTR (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2, varscan2
- CROCC | c.1808+870C>A | Intron (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- MTHFD1 | c.2279+37A>C | Intron (SNP) | VAF 91/279 reads (33%) | called by muse, mutect2, varscan2
- RBBP4 | c.1212+616A>T | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- SMTN | c.2603+1062G>A | Intron (SNP) | VAF 40/151 reads (26%) | catalogued as rs765152030; called by muse, mutect2, varscan2
- SOD1 | c.-33C>G | 5'UTR (SNP) | VAF 22/180 reads (12%) | catalogued as rs749428274, COSV54256572, COSV99531978; called by muse, mutect2
- TNFRSF10B | c.*1522T>G | 3'UTR (SNP) | VAF 108/834 reads (13%) | called by muse, mutect2, varscan2
- VSX1 | chr20:25071635 T>G | 3'Flank (SNP) | VAF 74/388 reads (19%) | called by muse, varscan2
